Somatic mutation profile of tumor specimen TCGA-2G-AALT-01A (aliquot TCGA-2G-AALT-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALT, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 772885e0-5a00-430f-8131-56a0ee16f227.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALT-10A (Blood Derived Normal), aliquot TCGA-2G-AALT-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0597e3-de49-4dd9-86ee-cf2dbac02b17

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Splice Site 1, Silent 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH2 | c.11345C>A p.A3782D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as rs762431493; called by muse, mutect2, varscan2
- MAPK10 | c.578C>A p.A193D (on ENST00000359221 / NM_001351625.2; = p.A231D on NM_002753.5) | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60381102; called by muse, mutect2, varscan2
- BAZ1B | c.1731_1732del p.K578Afs*3 | Frame Shift Del (DEL) | VAF 27/197 reads (14%) | called by mutect2, pindel, varscan2
- CEP85 | c.1038-1G>C p.X346_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ICE1 | c.2899C>T p.Q967* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- LRP1B | c.2618_2623dup p.G873_S874dup | In Frame Ins (INS) | VAF 17/78 reads (22%) | called by mutect2, varscan2
- AMMECR1L | c.445C>A p.R149= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs371126249; called by muse, mutect2, varscan2
- GPATCH2L | c.1053-68_1053-67del | Intron (DEL) | VAF 22/132 reads (17%) | catalogued as rs749495575; called by pindel, varscan2
